Somatic mutation profile of tumor specimen ALCH-B3D2-TTP1-A (aliquot ALCH-B3D2-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3D2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.7 years (27,665 days).
Specimen ALCH-B3D2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4028b42-3841-4eaa-92c6-380411041dce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3D2-NB1-A (Blood Derived Normal), aliquot ALCH-B3D2-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59d47cc-a793-409a-82ce-7325fecc1eee

The open-access MAF lists 476 somatic variants for this specimen: 323 protein-altering or splice-affecting, 87 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 87, Intron 33, Nonsense Mutation 28, Frame Shift Del 18, RNA 11, 5'Flank 8, 3'UTR 6, Frame Shift Ins 6, Splice Site 5, 5'UTR 4, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3586C>G p.H1196D (on ENST00000404938 / NM_001163941.2; = p.H751D on NM_178559.6) | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51705859; called by muse, mutect2, varscan2
- ACAN | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1259839311, COSV61363340; called by muse, mutect2, varscan2
- ACSM2A | c.314G>A p.R105H (on ENST00000219054; = p.R26H on NM_001308169.2) | Missense Mutation (SNP) | VAF 86/1155 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs371291843; called by muse, mutect2
- ACSM2B | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs577119435; called by muse, mutect2, varscan2
- ADAM20 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as rs748598801, COSV56454418; called by muse, mutect2, varscan2
- AFF3 | c.204del p.I69Sfs*5 | Frame Shift Del (DEL) | VAF 71/303 reads (23%) | catalogued as COSV100418838, COSV57860898; called by mutect2, pindel, varscan2
- AP5M1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1448093375; called by muse, mutect2, varscan2
- APC2 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs781314475; called by muse, mutect2, varscan2
- ATP11B | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1035182590, COSV60028053; called by muse, mutect2
- BPIFB4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 82/697 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs150695588; called by muse, mutect2, varscan2
- BRINP1 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 189/628 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56294043; called by muse, varscan2
- C16orf78 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 176/732 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.067); catalogued as rs774574783; called by muse, mutect2, varscan2
- CCDC83 | c.946A>G p.I316V (on ENST00000342404 / NM_001286159.2; = p.I347V on NM_173556.5) | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs759912714; called by muse, mutect2, varscan2
- CD93 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 218/549 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.264); catalogued as rs777956213, COSV99849739; called by muse, mutect2, varscan2
- CENPJ | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67883734; called by muse, mutect2, varscan2
- CFH | c.3405G>C p.E1135D | Missense Mutation (SNP) | VAF 326/1633 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs1255635424, CM109986; called by muse, mutect2, varscan2
- CHIT1 | c.508del p.A170Pfs*11 | Frame Shift Del (DEL) | VAF 366/1456 reads (25%) | catalogued as COSV55145311; called by mutect2, varscan2*
- CLEC4D | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 111/417 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV55229382; called by muse, mutect2, varscan2
- COL17A1 | c.530G>C p.R177P | Missense Mutation (SNP) | VAF 166/507 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV62225451; called by muse, mutect2, varscan2
- COL19A1 | c.2065G>T p.G689C | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780077270; called by muse, varscan2
- CRYBG3 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.076); catalogued as rs1279750691; called by muse, mutect2, varscan2
- CSMD3 | c.10827G>T p.L3609= (on ENST00000297405 / NM_001363185.1; = p.L3440= on NM_052900.3) | Splice Region (SNP) | VAF 154/458 reads (34%) | catalogued as COSV52174855, COSV99840019; called by muse, mutect2, varscan2
- CTAGE9 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 187/864 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58418435; called by muse, mutect2, varscan2
- CTNNA2 | c.540del p.E182Rfs*3 | Frame Shift Del (DEL) | VAF 55/376 reads (15%) | catalogued as COSV63592326; called by mutect2, pindel, varscan2
- CYP3A4 | c.146A>C p.N49T | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1259521795; called by muse, mutect2, varscan2
- DNAH11 | c.7723A>G p.I2575V | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as rs747351651; called by muse, mutect2, varscan2
- DPPA4 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 144/757 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs1199763519; called by muse, mutect2, varscan2
- EGF | c.3193A>G p.K1065E | Missense Mutation (SNP) | VAF 162/440 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV54475408; called by muse, mutect2, varscan2
- EPS8L1 | c.1474C>G p.R492G (on ENST00000201647 / NM_133180.3; = p.R365G on NM_017729.3) | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52381901; called by muse, mutect2, varscan2
- FANCM | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1016099459, COSV57501278; called by muse, mutect2, varscan2
- FAT4 | c.14143T>C p.Y4715H | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58700340; called by muse, mutect2, varscan2
- FDXR | c.682C>T p.R228W (on ENST00000293195 / NM_024417.5; = p.R234W on NM_004110.6) | Missense Mutation (SNP) | VAF 256/723 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377677821, COSV53113320; called by muse, mutect2, varscan2
- FNDC1 | c.2044C>G p.R682G | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1440002539; called by muse, mutect2, varscan2
- GPBP1L1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs781708812; called by muse, mutect2, varscan2
- GRXCR2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs952270962; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 330/1145 reads (29%) | catalogued as rs770428012; called by muse, mutect2, varscan2
- IRAK1 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs377582537, COSV64110599; called by muse, mutect2, varscan2
- KCNJ8 | c.375-2A>T p.X125_splice | Splice Site (SNP) | VAF 61/273 reads (22%) | catalogued as rs1355430987; called by muse, mutect2, varscan2
- KCNMA1 | c.3298G>T p.V1100L (on ENST00000286628 / NM_001161352.2; = p.V1042L on NM_002247.4) | Missense Mutation (SNP) | VAF 344/939 reads (37%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.447); catalogued as COSV54236263; called by muse, mutect2, varscan2
- KDM4C | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs780798863; called by muse, mutect2, varscan2
- KMT2D | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56464366, COSV99040336; called by muse, mutect2, varscan2
- KSR1 | c.881G>C p.R294P (on ENST00000644974 / NM_001367810.1; = p.R157P on NM_014238.2) | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52039073; called by muse, varscan2
- LAMC1 | c.287A>C p.Q96P | Missense Mutation (SNP) | VAF 301/1295 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs759363262, COSV99279776; called by muse, mutect2, varscan2
- LATS1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs771498477, COSV99486584; called by muse, mutect2, varscan2
- LCAT | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 478/1281 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV50454213; called by muse, mutect2, varscan2
- LHCGR | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 82/659 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559262616, COSV54293731, COSV99683806; called by muse, mutect2, varscan2
- LONRF2 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 105/505 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs201475623; called by muse, mutect2, varscan2
- LPIN3 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.237); catalogued as rs757556828; called by muse, mutect2, varscan2
- LYN | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 15/161 reads (9%) | catalogued as COSV70205606; called by muse, mutect2
- MAGEA3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 264/476 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as rs782041540, COSV64756629; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 97/178 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV66775187; called by muse, mutect2, varscan2
- MAMDC2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65857984; called by muse, mutect2, varscan2
- MAP3K13 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 142/2172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777869754, COSV53989572; called by muse, mutect2
- MCM6 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 66/205 reads (32%) | catalogued as COSV51467775; called by muse, mutect2, varscan2
- MDGA2 | c.2132C>A p.P711Q (on ENST00000399232 / NM_001113498.2; = p.P413Q on NM_182830.4) | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV62079033; called by muse, mutect2, varscan2
- MEI1 | c.1522T>C p.F508L | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs746360546; called by muse, mutect2, varscan2
- METTL4 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55247597; called by muse, mutect2, varscan2
- MGAT1 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 171/600 reads (29%) | PolyPhen probably damaging (1); catalogued as COSV57133719; called by muse, mutect2, varscan2
- MGAT5B | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 202/549 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV56937195; called by muse, mutect2, varscan2
- MROH5 | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 352/882 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1198342015; called by muse, mutect2, varscan2
- MRPS11 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 111/355 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1217364480; called by muse, mutect2, varscan2
- MSR1 | c.850C>G p.R284G | Missense Mutation (SNP) | VAF 64/500 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs762856785, COSV50518319; called by muse, mutect2, varscan2
- MX2 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 191/438 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs752037451; called by muse, mutect2, varscan2
- MYH1 | c.2602G>C p.A868P | Missense Mutation (SNP) | VAF 71/625 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV56847487, COSV56847827; called by muse, mutect2, varscan2
- MYH3 | c.3638G>A p.R1213Q | Missense Mutation (SNP) | VAF 250/1070 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs773055884; called by muse, mutect2, varscan2
- NAGPA | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 353/1134 reads (31%) | PolyPhen benign (0.005); catalogued as COSV56570972; called by muse, mutect2, varscan2
- NUBPL | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 175/812 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs749762773, COSV55277842; called by muse, mutect2, varscan2
- OPLAH | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 142/309 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1554757800, COSV101470964; called by muse, mutect2, varscan2
- OR10K2 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 297/747 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100149470; called by muse, mutect2, varscan2
- OR1S1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs758614473; called by muse, mutect2, varscan2
- OR2G2 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60740647; called by muse, mutect2, varscan2
- OR2M3 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 101/554 reads (18%) | catalogued as rs1437737043; called by muse, mutect2, varscan2
- OR52K2 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 114/776 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57834609, COSV57835187; called by muse, mutect2, varscan2
- OR5B12 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs767380041, COSV56904525; called by muse, mutect2, varscan2
- PCDH10 | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092050; called by muse, mutect2, varscan2
- PCSK5 | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 120/485 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763429672; called by muse, mutect2, varscan2
- PDE8B | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 34/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1002457386; called by muse, mutect2
- PKHD1L1 | c.9809G>A p.G3270D | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV65748479; called by muse, mutect2, varscan2
- PLCXD3 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV60608310; called by muse, mutect2, varscan2
- PLIN4 | c.2148G>C p.K716N (on ENST00000301286; = p.K731N on NM_001367868.2) | Missense Mutation (SNP) | VAF 186/2191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1345291267, COSV56687861; called by muse, mutect2
- PNLDC1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 118/441 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs377341454, COSV51703910, COSV99277200; called by muse, mutect2, varscan2
- PNLIPRP2 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 62/412 reads (15%) | catalogued as COSV53943708; called by muse, mutect2, varscan2
- POLL | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 171/475 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs1445065119; called by muse, mutect2, varscan2
- POTEG | c.882A>T p.K294N | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs778600698; called by muse, mutect2, varscan2
- PPP1R9A | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 42/250 reads (17%) | catalogued as COSV99194494, COSV99195276; called by muse, varscan2
- PTX3 | c.309C>A p.C103* | Nonsense Mutation (SNP) | VAF 140/722 reads (19%) | catalogued as rs568717634; called by muse, mutect2, varscan2
- RELT | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 142/506 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377396969; called by muse, mutect2, varscan2
- RGS6 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV59599056; called by muse, mutect2, varscan2
- ROBO3 | c.2221C>G p.Q741E | Missense Mutation (SNP) | VAF 175/578 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV101184864; called by muse, mutect2, varscan2
- RPS6KA1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 169/351 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768113135; called by muse, mutect2, varscan2
- RYR3 | c.10877C>T p.A3626V (on ENST00000389232; = p.A3627V on NM_001036.6) | Missense Mutation (SNP) | VAF 98/584 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755777324; called by muse, mutect2, varscan2
- SLCO4C1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 20/638 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1312466031, COSV60517698; called by muse, mutect2
- SLITRK3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 87/708 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs188339465; called by muse, mutect2, varscan2
- SPG11 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 193/548 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200939573, COSV55997076; called by muse, mutect2, varscan2
- SYNE1 | c.17014C>T p.R5672W (on ENST00000367255 / NM_182961.4; = p.R5601W on NM_033071.3) | Missense Mutation (SNP) | VAF 161/606 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780794124, COSV99573996; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SYNJ2 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 129/1016 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs199914000; called by muse, mutect2, varscan2
- TAS2R41 | c.723T>G p.I241M | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as rs765683243; called by muse, mutect2, varscan2
- TCN1 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 135/501 reads (27%) | catalogued as COSV57252601; called by muse, mutect2, varscan2
- TDRD5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV99675315; called by muse, mutect2, varscan2
- TET2 | c.5777G>A p.R1926H | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1316795626, COSV99484590; called by muse, mutect2
- TFDP3 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 146/267 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59539141; called by muse, mutect2, varscan2
- TFR2 | c.2206del p.R736Vfs*41 | Frame Shift Del (DEL) | VAF 43/212 reads (20%) | catalogued as COSV99774701; called by mutect2, pindel
- TRIM42 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 113/580 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV53885977; called by muse, mutect2, varscan2
- TRPC7 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1182478627, COSV61452031; called by muse, mutect2, varscan2
- TSHB | c.189del p.K64Nfs*19 | Frame Shift Del (DEL) | VAF 103/435 reads (24%) | catalogued as COSV56655151; called by mutect2, pindel, varscan2
- TSPYL5 | c.409del p.R137Afs*27 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as COSV59071699; called by pindel, varscan2
- TUT7 | c.2908C>T p.R970* | Nonsense Mutation (SNP) | VAF 27/250 reads (11%) | catalogued as COSV99462248; called by muse, mutect2, varscan2
- UGT1A7 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 180/674 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV60832268; called by muse, mutect2, varscan2
- UNC80 | c.6935C>A p.T2312N | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV55898449; called by muse, mutect2, varscan2
- USH1C | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 175/948 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.189); catalogued as rs1007641421, COSV50014771; called by muse, mutect2, varscan2
- USP33 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 55/197 reads (28%) | catalogued as rs988434291, COSV62469319; called by muse, mutect2, varscan2
- WNK1 | c.3758C>T p.S1253F (on ENST00000315939 / NM_018979.4; = p.S1006F on NM_014823.3) | Missense Mutation (SNP) | VAF 189/832 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60026017; called by muse, mutect2, varscan2
- XAB2 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100601816, COSV64321165; called by muse, mutect2
- ZFAND4 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58897936; called by muse, mutect2, varscan2
- ZFHX4 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as COSV51455559; called by muse, mutect2, varscan2
- ZNF142 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 135/659 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468872962; called by muse, mutect2, varscan2
- ZNF519 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as rs1268743517; called by muse, mutect2, varscan2
- ZNF692 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 413/1093 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs746369683; called by muse, mutect2, varscan2
- ZNF831 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100926231; called by muse, mutect2
- A2ML1 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 67/660 reads (10%) | called by muse, mutect2, varscan2
- ACAD11 | c.1545T>A p.D515E | Missense Mutation (SNP) | VAF 80/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ACAN | c.2541del p.V848Cfs*97 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.823A>T p.I275F | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG4 | c.2740A>T p.K914* | Nonsense Mutation (SNP) | VAF 91/176 reads (52%) | called by muse, mutect2, varscan2
- ADGRV1 | c.11773A>G p.I3925V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMY2B | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 214/779 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by mutect2, varscan2
- ANKRD1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 246/691 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP45 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.057); called by muse, mutect2
- ARHGEF38 | c.1055T>C p.L352S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARID1A | c.1010G>A p.W337* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- ASB4 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ASIC5 | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATN1 | c.1366A>C p.N456H | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, varscan2
- ATP6V1G1 | c.183G>T p.A61= | Splice Region (SNP) | VAF 102/357 reads (29%) | called by muse, mutect2, varscan2
- BATF2 | c.86_98del p.A29Efs*277 | Frame Shift Del (DEL) | VAF 125/666 reads (19%) | called by mutect2, pindel, varscan2
- BCLAF1 | c.1981A>T p.T661S | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- BRCC3 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTK | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BTNL9 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 202/714 reads (28%) | called by muse, mutect2, varscan2
- C17orf98 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 184/484 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C2orf16 | c.5895dup p.G1966Rfs*5 | Frame Shift Ins (INS) | VAF 40/190 reads (21%) | called by mutect2, pindel, varscan2
- CACNG3 | c.932_933del p.R311Hfs*7 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | called by pindel, varscan2
- CAMK4 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD84 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH10 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDH7 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDHR5 | c.705del p.W236Gfs*61 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, varscan2
- CDHR5 | c.704del p.P235Rfs*62 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2*, pindel, varscan2*
- CELSR1 | c.7738G>A p.G2580S | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFH | c.2489G>T p.R830L | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CGNL1 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNNM2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 92/422 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CNTNAP2 | c.3168C>G p.S1056R | Missense Mutation (SNP) | VAF 176/509 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- COL22A1 | c.4327C>T p.P1443S | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- COL4A1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 106/322 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL4A4 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- COL4A4 | c.1198T>A p.C400S | Missense Mutation (SNP) | VAF 124/410 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COL4A4 | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 202/833 reads (24%) | called by muse, mutect2, varscan2
- COL6A5 | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- CPE | c.956G>T p.W319L | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPE | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPNE6 | c.1511del p.F504Sfs*133 | Frame Shift Del (DEL) | VAF 209/711 reads (29%) | called by mutect2, pindel, varscan2
- CPXM2 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 163/877 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CRB1 | c.1435C>A p.L479M | Missense Mutation (SNP) | VAF 84/529 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSMD3 | c.6193G>T p.G2065* (on ENST00000297405 / NM_001363185.1; = p.G1961* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 92/633 reads (15%) | called by muse, mutect2, varscan2
- CTNND2 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 132/553 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DACH2 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DIAPH2 | c.573del p.S192Afs*50 | Frame Shift Del (DEL) | VAF 77/219 reads (35%) | called by mutect2, pindel, varscan2
- DIS3 | c.2143A>T p.T715S | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- DNAH6 | c.3227A>T p.Y1076F | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DNASE1 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 210/712 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- DPYSL2 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 146/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DSE | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 90/538 reads (17%) | called by muse, mutect2, varscan2
- DYSF | c.4862G>A p.C1621Y | Missense Mutation (SNP) | VAF 184/580 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EFCC1 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 557/756 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ELF1 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F13A1 | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 142/870 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- FANCM | c.5015A>T p.D1672V | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FBN1 | c.4712G>T p.G1571V | Missense Mutation (SNP) | VAF 99/665 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCHSD1 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRLB | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FLT1 | c.1277-1G>T p.X426_splice | Splice Site (SNP) | VAF 87/486 reads (18%) | called by muse, mutect2, varscan2
- FOLH1 | c.1984A>G p.R662G | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FOXL2 | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FSCB | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 126/582 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FSIP2 | c.18731C>A p.A6244D | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FUS | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 26/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- GAPVD1 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GOLGA6L2 | c.958del p.E320Rfs*658 | Frame Shift Del (DEL) | VAF 59/453 reads (13%) | called by mutect2, pindel, varscan2
- GPS1 | c.1081del p.H361Mfs*44 | Frame Shift Del (DEL) | VAF 117/619 reads (19%) | called by mutect2, pindel, varscan2
- GRM5 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 101/520 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GYS2 | c.902A>T p.K301M | Missense Mutation (SNP) | VAF 135/503 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAAO | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- HCN1 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 86/394 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HCRTR2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 286/925 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HHLA1 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 76/423 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNRNPUL2 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 148/563 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- IGF2 | c.326-3del | Splice Region (DEL) | VAF 130/919 reads (14%) | called by mutect2, pindel, varscan2
- IKBIP | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2
- IL21 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNG2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KCNMA1 | c.1290C>A p.H430Q | Missense Mutation (SNP) | VAF 167/912 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN2 | c.682C>T p.P228S (on ENST00000264773; = p.P440S on NM_021614.4) | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNN4 | c.608A>G p.H203R | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- KIF17 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 328/644 reads (51%) | called by muse, mutect2, varscan2
- KIF21B | c.4331A>T p.Q1444L (on ENST00000422435 / NM_001252100.2; = p.Q1431L on NM_017596.4) | Missense Mutation (SNP) | VAF 140/503 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- KLF17 | c.300C>A p.Y100* | Nonsense Mutation (SNP) | VAF 50/237 reads (21%) | called by muse, mutect2, varscan2
- KLHL33 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- KRT16P2 | n.536C>A | Splice Region (SNP) | VAF 133/1273 reads (10%) | called by muse, mutect2, varscan2
- KRT76 | c.550C>G p.R184G | Missense Mutation (SNP) | VAF 191/616 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LDAH | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LIMA1 | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 85/323 reads (26%) | called by muse, mutect2, varscan2
- LIMS1 | c.39C>A p.C13* | Nonsense Mutation (SNP) | VAF 217/1006 reads (22%) | called by muse, mutect2, varscan2
- LRFN5 | c.1320T>A p.N440K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRP2 | c.5508T>A p.Y1836* | Nonsense Mutation (SNP) | VAF 170/626 reads (27%) | called by muse, mutect2, varscan2
- LRRC10B | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 122/491 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- LRRC4C | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 71/500 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LVRN | c.2375G>A p.C792Y | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYPD6B | c.219C>G p.N73K (on ENST00000409029 / NM_001317004.1; = p.N97K on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- LYPD8 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 179/594 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACF1 | c.13192A>G p.M4398V (on ENST00000372915; = p.M2331V on NM_012090.5) | Missense Mutation (SNP) | VAF 110/631 reads (17%) | called by muse, mutect2, varscan2
- MAFA | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 76/858 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MAN1A1 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 39/286 reads (14%) | called by muse, mutect2, varscan2
- MCCC2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 191/760 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKRN3 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 241/733 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MLLT6 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 139/443 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMP28 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPLKIP | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 242/779 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- MUC16 | c.28034C>T p.T9345I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC5B | c.16721_16740del p.E5574Afs*23 | Frame Shift Del (DEL) | VAF 74/542 reads (14%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.864T>G p.N288K (on ENST00000550270 / NM_206820.2; = p.N313K on NM_002465.4) | Missense Mutation (SNP) | VAF 248/999 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH15 | c.2812G>T p.V938L | Missense Mutation (SNP) | VAF 164/1051 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYH2 | c.2879T>A p.I960N | Missense Mutation (SNP) | VAF 114/673 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MYH7B | c.2521C>A p.R841S | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1A | c.3106C>T p.H1036Y | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2
- NAV1 | c.2454_2459del p.H819_A820del | In Frame Del (DEL) | VAF 115/792 reads (15%) | called by mutect2, pindel, varscan2
- NCKAP1L | c.1388T>A p.V463D | Missense Mutation (SNP) | VAF 145/512 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFATC4 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- NOTCH4 | c.5447T>C p.L1816P | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- NPAP1 | c.3306G>T p.M1102I | Missense Mutation (SNP) | VAF 102/547 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NWD2 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 376/811 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- NXPH1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OPALIN | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR10G8 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 115/391 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2F2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4D11 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR51B5 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- OR5H1 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- OTUD7A | c.2110A>G p.R704G (on ENST00000307050 / NM_001382637.1; = p.R697G on NM_130901.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PCDH11Y | c.1267G>T p.D423Y (on ENST00000400457 / NM_032973.2; = p.D412Y on NM_032971.3) | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- PCDHA1 | c.1579del p.E527Sfs*9 | Frame Shift Del (DEL) | VAF 291/1385 reads (21%) | called by mutect2, pindel, varscan2
- PDIA2 | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 123/584 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PEX13 | c.1122A>T p.E374D | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PIEZO2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLA2G2D | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PLG | c.1625G>C p.W542S | Missense Mutation (SNP) | VAF 100/645 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PNMA2 | c.547G>T p.V183F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- POTEC | c.1268G>C p.G423A | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PPFIBP2 | c.218_219insA p.L74Pfs*17 | Frame Shift Ins (INS) | VAF 276/874 reads (32%) | called by mutect2, pindel, varscan2
- PRB2 | c.1245_1246del p.Q416Vfs*8 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- PRX | c.2126T>C p.V709A | Missense Mutation (SNP) | VAF 252/1081 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PXDN | c.201-10_204del p.X67_splice | Splice Site (DEL) | VAF 71/380 reads (19%) | called by mutect2, pindel, varscan2
- PXDNL | c.3403G>C p.V1135L | Missense Mutation (SNP) | VAF 118/675 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB5A | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- RANBP2 | c.7381G>T p.E2461* | Nonsense Mutation (SNP) | VAF 192/1305 reads (15%) | called by muse, mutect2, varscan2
- RBMXL3 | c.3062C>A p.P1021Q | Missense Mutation (SNP) | VAF 167/296 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RBP3 | c.1769C>G p.A590G | Missense Mutation (SNP) | VAF 206/571 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- REXO5 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 122/519 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RIPOR2 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNF135 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 40/976 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ROBO2 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RUFY4 | c.1503-1G>C p.X501_splice | Splice Site (SNP) | VAF 68/282 reads (24%) | called by mutect2, varscan2
- SELE | c.1177A>C p.S393R | Missense Mutation (SNP) | VAF 113/608 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SGCZ | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 129/513 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SGPL1 | c.1635C>G p.F545L | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SGTA | c.407G>C p.S136T | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- SI | c.4645G>T p.G1549* | Nonsense Mutation (SNP) | VAF 97/767 reads (13%) | called by muse, mutect2, varscan2
- SIPA1 | c.189dup p.T64Hfs*28 | Frame Shift Ins (INS) | VAF 80/280 reads (29%) | called by mutect2, varscan2
- SLC16A11 | c.506C>A p.A169E (on ENST00000308009; = p.A145E on NM_153357.3) | Missense Mutation (SNP) | VAF 101/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SLC18A2 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SLC24A4 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SLC26A7 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- SLC9B1 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN12L | c.896G>C p.C299S (on ENST00000260908 / NM_001363830.1; = p.C317S on NM_001195790.1) | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SPANXN4 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SPATA48 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- STAC2 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 137/344 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STARD13 | c.2567G>C p.G856A (on ENST00000336934 / NM_001243476.3; = p.G738A on NM_052851.3) | Missense Mutation (SNP) | VAF 100/383 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- STK32A | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STYXL2 | c.2785A>G p.K929E | Missense Mutation (SNP) | VAF 70/674 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- SUCO | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SUSD2 | c.1901A>C p.H634P | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYT14 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TARBP1 | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 50/537 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TARBP1 | c.950G>T p.W317L | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TARS2 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 68/315 reads (22%) | called by muse, mutect2, varscan2
- TAS2R41 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TEX13C | c.2919G>C p.K973N | Missense Mutation (SNP) | VAF 140/235 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- THBS4 | c.1970A>G p.D657G | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THEMIS | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLN2 | c.1102A>T p.S368C | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.1657C>A p.L553I (on ENST00000355622 / NM_138554.5; = p.L513I on NM_003266.4) | Missense Mutation (SNP) | VAF 114/456 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TMED6 | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 226/879 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TOPAZ1 | c.2452dup p.S818Kfs*7 | Frame Shift Ins (INS) | VAF 103/378 reads (27%) | called by pindel, varscan2
- TRIM13 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRIM39 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 87/549 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TRPV4 | c.1865dup p.L622Ffs*26 | Frame Shift Ins (INS) | VAF 398/1464 reads (27%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 113/537 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBQLN3 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 171/385 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UNC45B | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 199/495 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UNC5D | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2
- USP9X | c.6383dup p.L2128Ffs*17 | Frame Shift Ins (INS) | VAF 153/330 reads (46%) | called by mutect2, pindel, varscan2
- VCAN | c.2030A>T p.Q677L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- VEPH1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 201/1275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13C | c.5018A>T p.Q1673L (on ENST00000644861 / NM_020821.3; = p.Q1630L on NM_017684.5) | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS72 | c.547A>T p.N183Y | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XAB2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2
- YRDC | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZMAT1 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.067); called by muse, mutect2
- ZNF202 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- ZNF521 | c.1345C>A p.L449I | Missense Mutation (SNP) | VAF 185/597 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF81 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- A1CF | c.535C>A p.R179= | Silent (SNP) | VAF 63/208 reads (30%) | catalogued as COSV51027342; called by muse, mutect2, varscan2
- ABCC9 | c.975G>A p.V325= | Silent (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1731G>A p.A577= | Silent (SNP) | VAF 143/729 reads (20%) | catalogued as rs370752253; called by muse, mutect2, varscan2
- AKAP1 | c.1740C>T p.S580= | Silent (SNP) | VAF 51/392 reads (13%) | catalogued as rs201653507, COSV58471348; called by muse, mutect2, varscan2
- ARFGAP2 | c.843C>A p.L281= | Silent (SNP) | VAF 40/300 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.1647C>A p.P549= | Silent (SNP) | VAF 103/421 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.234C>A p.P78= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV62725881; called by muse, mutect2, varscan2
- BEST4 | c.1104C>T p.A368= | Silent (SNP) | VAF 54/388 reads (14%) | catalogued as COSV100944033; called by muse, mutect2, varscan2
- BTNL8 | c.805C>T p.L269= (on ENST00000340184 / NM_001040462.3; = p.T312I on NM_024850.2) | Silent (SNP) | VAF 248/758 reads (33%) | catalogued as rs753067735; called by muse, mutect2, varscan2
- CACNA1C | c.3498C>T p.I1166= | Silent (SNP) | VAF 184/655 reads (28%) | catalogued as rs201147949, COSV100219454; ClinVar: likely benign; called by muse, mutect2, varscan2
- CFHR3 | c.51T>C p.N17= | Silent (SNP) | VAF 232/725 reads (32%) | called by muse, mutect2, varscan2
- CNOT2 | c.135C>T p.S45= | Silent (SNP) | VAF 40/208 reads (19%) | called by muse, varscan2
- COL6A6 | c.2539C>A p.R847= | Silent (SNP) | VAF 454/666 reads (68%) | catalogued as rs539130714; called by muse, mutect2, varscan2
- CSMD1 | c.4971G>A p.T1657= (on ENST00000520002; = p.T1656= on NM_033225.6) | Silent (SNP) | VAF 83/204 reads (41%) | catalogued as rs371736115, COSV100152999; called by muse, mutect2, varscan2
- CTNNA2 | c.2286G>A p.V762= | Silent (SNP) | VAF 107/367 reads (29%) | called by muse, mutect2, varscan2
- CTNND2 | c.1491C>T p.S497= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as COSV58882979; called by muse, mutect2, varscan2
- CTXN1 | c.240G>T p.A80= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- DENND5A | c.1296C>T p.A432= | Silent (SNP) | VAF 117/669 reads (17%) | catalogued as rs1055122456; called by muse, mutect2, varscan2
- DNMT1 | c.3894G>T p.V1298= | Silent (SNP) | VAF 457/1115 reads (41%) | called by muse, mutect2, varscan2
- DNMT1 | c.501C>T p.I167= | Silent (SNP) | VAF 151/1058 reads (14%) | called by muse, varscan2
- DOK5 | c.321C>A p.L107= | Silent (SNP) | VAF 85/183 reads (46%) | catalogued as COSV52815891; called by muse, mutect2, varscan2
- DPP10 | c.282G>T p.V94= | Silent (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
- DPP6 | c.1765C>A p.R589= (on ENST00000377770 / NM_001364500.2; = p.R527= on NM_001936.5) | Silent (SNP) | VAF 62/326 reads (19%) | called by muse, mutect2, varscan2
- EBF2 | c.186G>A p.R62= | Silent (SNP) | VAF 60/494 reads (12%) | catalogued as rs776120174, COSV68779592; called by muse, mutect2, varscan2
- EPHA6 | c.1614C>A p.S538= | Silent (SNP) | VAF 84/391 reads (21%) | called by muse, mutect2, varscan2
- FAT3 | c.8409G>A p.K2803= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV53121139; called by muse, mutect2, varscan2
- FOXG1 | c.1335G>A p.P445= | Silent (SNP) | VAF 259/610 reads (42%) | catalogued as COSV57395563; called by muse, mutect2, varscan2
- FREM3 | c.4770C>T p.S1590= | Silent (SNP) | VAF 90/200 reads (45%) | called by muse, mutect2, varscan2
- GCOM1 | c.621G>A p.R207= | Silent (SNP) | VAF 206/702 reads (29%) | catalogued as COSV51094831; called by muse, mutect2, varscan2
- GRIK1 | c.963G>T p.A321= | Silent (SNP) | VAF 111/250 reads (44%) | called by muse, mutect2, varscan2
- HMGA2 | c.321A>G p.E107= | Silent (SNP) | VAF 170/655 reads (26%) | called by muse, mutect2, varscan2
- IL20RA | c.1131G>A p.T377= | Silent (SNP) | VAF 200/772 reads (26%) | catalogued as rs755160359, COSV100359809; called by muse, mutect2
- KANSL1 | c.1036C>T p.L346= | Silent (SNP) | VAF 55/313 reads (18%) | catalogued as rs1047432968; called by muse, mutect2, varscan2
- KCNC2 | c.1407G>T p.V469= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- KHDC1L | c.315T>G p.R105= | Silent (SNP) | VAF 78/350 reads (22%) | called by muse, mutect2, varscan2
- LRFN2 | c.960C>A p.I320= | Silent (SNP) | VAF 71/322 reads (22%) | called by muse, mutect2, varscan2
- MED12L | c.5574A>G p.L1858= | Silent (SNP) | VAF 273/2279 reads (12%) | catalogued as rs374617628; called by muse, mutect2, varscan2
- MRGPRX3 | c.171C>G p.R57= | Silent (SNP) | VAF 88/360 reads (24%) | called by muse, mutect2, varscan2
- MUC19 | c.1219A>C p.R407= | Silent (SNP) | VAF 89/331 reads (27%) | called by muse, mutect2, varscan2
- MUC5B | c.11718C>A p.P3906= | Silent (SNP) | VAF 285/1061 reads (27%) | called by muse, mutect2, varscan2
- NEK5 | c.300T>C p.F100= | Silent (SNP) | VAF 70/179 reads (39%) | called by muse, mutect2, varscan2
- NUP160 | c.423G>T p.G141= | Silent (SNP) | VAF 39/192 reads (20%) | called by muse, mutect2, varscan2
- OLFM3 | c.27C>G p.G9= | Silent (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- OR4A15 | c.729T>A p.T243= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- OR4D11 | c.171C>G p.T57= | Silent (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- OR51M1 | c.840C>A p.A280= | Silent (SNP) | VAF 117/716 reads (16%) | catalogued as COSV60784171; called by muse, mutect2, varscan2
- OR5H2 | c.579C>T p.S193= | Silent (SNP) | VAF 67/246 reads (27%) | catalogued as COSV62350110; called by muse, mutect2, varscan2
- OR6V1 | c.153C>G p.T51= | Silent (SNP) | VAF 180/589 reads (31%) | catalogued as COSV69237785; called by muse, mutect2, varscan2
- ORC3 | c.1494G>T p.L498= | Silent (SNP) | VAF 73/190 reads (38%) | called by muse, mutect2, varscan2
- OTOF | c.3015C>A p.P1005= (on ENST00000272371 / NM_194248.3; = p.P258= on NM_004802.4) | Silent (SNP) | VAF 114/432 reads (26%) | catalogued as COSV55495078; called by muse, mutect2, varscan2
- OTOGL | c.3369G>A p.E1123= (on ENST00000547103; = p.E1114= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 55/273 reads (20%) | called by muse, mutect2, varscan2
- OTUD7B | c.2172A>C p.L724= | Silent (SNP) | VAF 65/256 reads (25%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4629G>A p.Q1543= | Silent (SNP) | VAF 387/1058 reads (37%) | called by muse, mutect2, varscan2
- PEG3 | c.3672C>A p.A1224= | Silent (SNP) | VAF 130/238 reads (55%) | called by muse, mutect2, varscan2
- PER1 | c.3387C>A p.P1129= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100424598; called by muse, mutect2, varscan2
- PHLDB1 | c.1230A>T p.P410= | Silent (SNP) | VAF 317/1005 reads (32%) | called by muse, mutect2, varscan2
- PKDREJ | c.345G>A p.L115= | Silent (SNP) | VAF 53/163 reads (33%) | called by muse, mutect2, varscan2
- PTRHD1 | c.24C>A p.A8= | Silent (SNP) | VAF 94/279 reads (34%) | called by muse, mutect2, varscan2
- RD3 | c.360G>T p.S120= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- RET | c.3258G>T p.G1086= | Silent (SNP) | VAF 171/798 reads (21%) | called by muse, mutect2, varscan2
- RETREG3 | c.918A>G p.Q306= | Silent (SNP) | VAF 121/319 reads (38%) | catalogued as rs1216580039; called by muse, mutect2, varscan2
- RUSC2 | c.1374A>G p.Q458= | Silent (SNP) | VAF 205/472 reads (43%) | catalogued as rs1232047804; called by muse, mutect2, varscan2
- RYR2 | c.1866G>C p.G622= | Silent (SNP) | VAF 185/879 reads (21%) | catalogued as COSV100773289; called by muse, mutect2, varscan2
- SACM1L | c.1374C>T p.D458= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- SERPINA12 | c.756C>T p.D252= | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as rs761146045; called by muse, mutect2, varscan2
- SI | c.4443A>G p.V1481= | Silent (SNP) | VAF 184/1294 reads (14%) | catalogued as rs1466650717; called by muse, mutect2, varscan2
- SLC18A1 | c.714G>A p.L238= | Silent (SNP) | VAF 354/839 reads (42%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1212C>T p.F404= | Silent (SNP) | VAF 52/316 reads (16%) | catalogued as rs555896287, COSV57927651; called by muse, mutect2, varscan2
- SLC26A2 | c.1230C>T p.Y410= | Silent (SNP) | VAF 78/507 reads (15%) | catalogued as rs759662003; called by muse, mutect2, varscan2
- SLC5A4 | c.699C>A p.T233= | Silent (SNP) | VAF 99/295 reads (34%) | called by muse, mutect2, varscan2
- SNAPC2 | c.483A>G p.E161= | Silent (SNP) | VAF 144/472 reads (31%) | catalogued as rs758383443; called by muse, mutect2, varscan2
- STYXL2 | c.2512C>A p.R838= | Silent (SNP) | VAF 282/729 reads (39%) | catalogued as COSV54810451; called by muse, mutect2, varscan2
- SYT11 | c.829C>T p.L277= | Silent (SNP) | VAF 114/234 reads (49%) | called by muse, varscan2
- SYT4 | c.63C>T p.F21= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- TACR3 | c.570C>A p.P190= | Silent (SNP) | VAF 91/290 reads (31%) | catalogued as rs146292386; called by muse, mutect2, varscan2
- THSD7B | c.3669C>T p.S1223= (on ENST00000272643; = p.S1221= on NM_001316349.2) | Silent (SNP) | VAF 110/342 reads (32%) | called by muse, mutect2, varscan2
- TNK2 | c.1842G>T p.R614= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as rs751027357; called by muse, mutect2, varscan2
- TRAFD1 | c.861C>T p.D287= | Silent (SNP) | VAF 72/382 reads (19%) | catalogued as rs1487505991; called by muse, mutect2, varscan2
- TRIM21 | c.360C>T p.H120= | Silent (SNP) | VAF 44/296 reads (15%) | catalogued as rs746385903, COSV54342641; called by muse, mutect2
- TSPAN15 | c.6G>T p.P2= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- TTBK1 | c.1485G>A p.Q495= | Silent (SNP) | VAF 61/186 reads (33%) | called by muse, mutect2, varscan2
- TTC6 | c.3057T>C p.A1019= | Silent (SNP) | VAF 92/429 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.2730C>A p.T910= (on ENST00000591111; = p.T864= on NM_003319.4) | Silent (SNP) | VAF 165/607 reads (27%) | called by muse, mutect2, varscan2
- USP19 | c.129A>G p.T43= | Silent (SNP) | VAF 80/158 reads (51%) | called by muse, mutect2, varscan2
- ZFP62 | c.582G>A p.E194= (on ENST00000502412 / NM_001377944.1; = p.E161= on NM_152283.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 62/211 reads (29%) | catalogued as rs1362229818; called by muse, mutect2, varscan2
- ZFP82 | c.1596C>T p.I532= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, varscan2
- ZNF496 | c.1365G>A p.E455= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as rs769986993, COSV54180315; called by muse, mutect2, varscan2
- AC009093.3 | chr16:29102085 C>A | 3'Flank (SNP) | VAF 122/486 reads (25%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-11349G>A | Intron (SNP) | VAF 60/232 reads (26%) | catalogued as rs1194656057; called by muse, mutect2, varscan2
- AGXT2 | chr5:35049151 C>A | 5'Flank (SNP) | VAF 86/232 reads (37%) | called by muse, mutect2, varscan2
- AKNA | c.-113-6433G>A | Intron (SNP) | VAF 46/184 reads (25%) | catalogued as rs1474266802; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826765 T>C | 3'Flank (SNP) | VAF 71/122 reads (58%) | called by muse, varscan2
- AL772337.1 | n.610G>T | RNA (SNP) | VAF 200/683 reads (29%) | called by muse, mutect2, varscan2
- ALDH2 | c.115-6268A>G | Intron (SNP) | VAF 87/398 reads (22%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.900G>A | RNA (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2156-3650T>A | Intron (SNP) | VAF 42/504 reads (8%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916127 G>T | 5'Flank (SNP) | VAF 123/468 reads (26%) | called by muse, mutect2, varscan2
- BOD1P2 | n.158C>G | RNA (SNP) | VAF 61/206 reads (30%) | called by muse, mutect2, varscan2
- CCDC93 | c.1351-652C>T | Intron (SNP) | VAF 126/422 reads (30%) | called by muse, mutect2, varscan2
- CD96 | c.*24C>A | 3'UTR (SNP) | VAF 123/617 reads (20%) | called by muse, mutect2, varscan2
- CFAP251 | c.2771+3411A>T | Intron (SNP) | VAF 145/610 reads (24%) | called by muse, mutect2, varscan2
- CHI3L2 | c.*24del | 3'UTR (DEL) | VAF 40/314 reads (13%) | called by mutect2, pindel, varscan2
- CSMD3 | c.-12C>A | 5'UTR (SNP) | VAF 114/634 reads (18%) | catalogued as rs1173445550, COSV99832760, COSV99835335; called by muse, mutect2, varscan2
- CYB5R2 | chr11:7674383 G>T | 5'Flank (SNP) | VAF 154/582 reads (26%) | called by muse, mutect2, varscan2
- CYTH4 | c.808+688G>A | Intron (SNP) | VAF 24/408 reads (6%) | catalogued as rs992723994; called by muse, mutect2
- EFHB | chr3:19936288 G>A | 5'Flank (SNP) | VAF 47/84 reads (56%) | catalogued as rs994695408; called by muse, mutect2, varscan2
- ETS1 | chr11:128526980 G>C | 5'Flank (SNP) | VAF 92/264 reads (35%) | called by muse, mutect2, varscan2
- FABP7 | c.348+96C>T | Intron (SNP) | VAF 96/309 reads (31%) | catalogued as rs555453817; called by muse, mutect2, varscan2
- FOXP2 | c.*3038C>T | 3'UTR (SNP) | VAF 67/191 reads (35%) | called by muse, mutect2, varscan2
- GRIA4 | c.2544+29C>A | Intron (SNP) | VAF 45/407 reads (11%) | catalogued as rs1413455012; called by muse, mutect2, varscan2
- GVINP1 | n.5711G>T | RNA (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- GYG2P1 | n.450+3833T>A | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- HLA-V | chr6:29792204 C>A | 5'Flank (SNP) | VAF 155/753 reads (21%) | called by muse, mutect2, varscan2
- IL12RB1 | c.*42_*43insT | 3'UTR (INS) | VAF 278/775 reads (36%) | called by mutect2, pindel, varscan2
- JAZF1 | c.116-28628G>T | Intron (SNP) | VAF 68/521 reads (13%) | called by muse, mutect2, varscan2
- KCNT2 | c.2349-1218G>C | Intron (SNP) | VAF 29/140 reads (21%) | catalogued as COSV54065345; called by muse, mutect2, varscan2
- LCP2 | c.324+14G>A | Intron (SNP) | VAF 90/464 reads (19%) | called by muse, varscan2
- LINC01148 | n.421G>C | RNA (SNP) | VAF 8/52 reads (15%) | catalogued as rs1157103932; called by muse, mutect2, varscan2
- LRCH1 | c.1654+3009G>T | Intron (SNP) | VAF 58/255 reads (23%) | catalogued as COSV60844826; called by muse, mutect2, varscan2
- LRRIQ3 | c.707+11196A>T | Intron (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- MLPH | c.*125G>T | 3'UTR (SNP) | VAF 121/464 reads (26%) | called by muse, mutect2, varscan2
- MON2 | chr12:62603164 A>T | 3'Flank (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- MUC19 | c.271-18C>A | Intron (SNP) | VAF 36/160 reads (23%) | called by muse, varscan2
- NBPF22P | n.542G>T | RNA (SNP) | VAF 72/270 reads (27%) | called by muse, mutect2, varscan2
- NRG3 | c.824-125929C>A | Intron (SNP) | VAF 69/508 reads (14%) | catalogued as rs1316423123; called by muse, mutect2, varscan2
- OBSCN | c.18662-2111G>C | Intron (SNP) | VAF 111/274 reads (41%) | called by muse, mutect2, varscan2
- OR2U1P | n.33G>T | RNA (SNP) | VAF 17/104 reads (16%) | catalogued as rs576089022; called by muse, mutect2, varscan2
- OR7E5P | n.672G>T | RNA (SNP) | VAF 79/239 reads (33%) | catalogued as rs555444804; called by muse, mutect2
- PAQR6 | c.180-67T>A | Intron (SNP) | VAF 463/1079 reads (43%) | called by muse, mutect2, varscan2
- PAX6 | c.358-14G>T | Intron (SNP) | VAF 328/1101 reads (30%) | called by muse, mutect2, varscan2
- PCID2 | c.-15T>A | 5'UTR (SNP) | VAF 178/527 reads (34%) | called by muse, mutect2, varscan2
- PRKRA | c.65+98C>G | Intron (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- PTEN | c.1026+50A>G | Intron (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2
- RBFOX1 | c.1071+460C>T | Intron (SNP) | VAF 74/380 reads (19%) | catalogued as rs776880018; called by muse, mutect2, varscan2
- REL | c.-36G>A | 5'UTR (SNP) | VAF 103/358 reads (29%) | catalogued as rs1488160733; called by muse, mutect2, varscan2
- RIPPLY3 | c.*61C>T | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20570835 C>A | 5'Flank (SNP) | VAF 309/2139 reads (14%) | called by muse, mutect2, varscan2
- RN7SL759P | chr15:20572614 A>G | 3'Flank (SNP) | VAF 302/1818 reads (17%) | called by mutect2, varscan2
- SGCD | c.-1+2319G>T | Intron (SNP) | VAF 56/277 reads (20%) | catalogued as rs752924735; called by muse, mutect2, varscan2
- SKOR1 | chr15:67822152 G>T | 5'Flank (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1648-21C>A | Intron (SNP) | VAF 73/304 reads (24%) | catalogued as rs759075632; called by muse, mutect2, varscan2
- SMARCA4 | c.3546+43T>C | Intron (SNP) | VAF 236/685 reads (34%) | called by muse, mutect2, varscan2
- SMIM22 | n.436C>A | RNA (SNP) | VAF 90/304 reads (30%) | called by muse, mutect2, varscan2
- SNED1 | c.3590-58C>G | Intron (SNP) | VAF 82/283 reads (29%) | called by muse, mutect2, varscan2
- SNX32 | c.141+140G>T | Intron (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3612G>T | RNA (SNP) | VAF 380/1321 reads (29%) | called by muse, mutect2, varscan2
- SPECC1L | c.-7G>A | 5'UTR (SNP) | VAF 145/611 reads (24%) | called by muse, mutect2, varscan2
- SRL | c.62-2368G>A | Intron (SNP) | VAF 60/205 reads (29%) | called by muse, mutect2, varscan2
- SSPOP | n.9037del | RNA (DEL) | VAF 54/404 reads (13%) | called by mutect2, varscan2
- TMEM161B | c.290-1015G>A | Intron (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10361-4085G>T | Intron (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- UPF3A | c.208-50C>T | Intron (SNP) | VAF 131/401 reads (33%) | catalogued as rs1285759792; called by muse, mutect2, varscan2
- UVRAG | c.1398-3387T>A | Intron (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
